Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9Z7, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9Z7-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

ICD O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1/28/14

FINAL PATHOLOGIC DIAGNOSIS

- A. Anterior prostatic fat, resection: Benign adipose tissue; no carcinoma or prostatic epithelium.
- B. Tissue anterior to seminal vesicles, excision: Focal crushed cells positive for keratin, suspicious for carcinoma; see comment.
- C. Right pelvic lymph nodes, dissection: No tumor in six lymph nodes (0/6).
- D. Left pelvic lymph nodes, dissection: No tumor in four lymph nodes (0/4).
- E. Prostate and seminal vesicles, radical prostatectomy:
- 1. Prostatic adenocarcinoma, Gleason score 5+4=9, invading into bilateral seminal vesicles; see comment.
- 2. Focal crushed cells weakly positive for keratin at bladder margin; see comment.

COMMENT:

Part B, the "tissue anterior to seminal vesicle", demonstrates a small focus of crushed cells within collagenous stroma at the black-inked edge of the specimen. Immunohistochemical stain for pancytokeratin on block B1 was performed and highlights these cells, supporting that they represent epithelial cells. However, the cytomorphology is too hampered by crush artifact to determine whether these are benign or malignant epithelial cells. The overall architectural pattern appears infiltrative, and therefore, suspicious for carcinoma, although definitive diagnosis cannot be rendered.

Similarly, the right bladder margin (slide E15) demonstrates a small focus of crushed/cauterized cells at the inked margin, directly adjacent to deeper bona fide tumor cells. Immunohistochemical stain for pancytokeratin on block E15 was performed, which is strongly positive in the tumor cells but weakly positive in the crushed/cauterized cells. These findings are equivocal for the presence of tumor cells at the bladder margin.

Synoptic Comment for Prostate Tumors

[page 2 of 3]
-
- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:**
- Left apex (slide E2).
- Left posterior mid gland (slides E9-E11).
- Left anterior mid gland (slides E12-E14).
- Right posterior mid gland (slides E6-E8).
- Right anterior mid gland (slides E3-E5).
- Right base (slide E15).
- **Estimated volume of tumor:** 9.3 cubic cm.
- **Gleason score:** 5+4=9.
- **Estimated volume > Gleason pattern 3:** Approximately 95%.
- **Involvement of capsule:** Tumor invades capsule (slides E5-E11).
- **Extraprostatic extension:** Present, extensive (slides E7-E8, E11, E17-E18).
- **Margin status for tumor:** Equivocal; see comment above.
- **Margin status for benign prostate glands:** No benign glands present at inked excision margins.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** Present; extensive.
- **Tumor involvement of seminal vesicle:** Present; both sides.
- **Perineural infiltration:** Present.
- **Lymphovascular invasion:** Present.
- **Lymph node status:** Negative; total number of nodes examined: 10.
- **AJCC/UICC stage:** pT3bN0.
-

Specimen(s) Received

A:Anterior prostatic fat
B:Tissue anterior to seminal vesicles
C:Right pelvic lymph nodes
D:Left pelvic lymph nodes
E:Prostate and seminal vesicles (fresh)

Clinical History

The patient is a 69-year-old man with a history of prostate cancer, Gleason score 5+4=9, who now undergoes prostatectomy.

Gross Description

The case is received in five parts, labeled with the patient's name and medical record number.

Part A is received in formalin and additionally labeled "anterior prostatic fat," and consists of multiple, irregular, unoriented fragments of brown-yellow, soft fatty tissue (4.2 x 3.4 x 1.5 cm in aggregate). One lymph node is identified in the specimen and is submitted with a representative sections of the fat in cassette A1.

Part B is received in formalin and additionally labeled "tissue anterior to seminal vesicle," and consists of a 1 x 1 x 0.4 cm, brown-tan, rubbery, irregular unoriented fragment of tissue. It is inked black, serially sectioned, and entirely submitted in cassette B1.

Part C is received in formalin and additionally labeled "right pelvic lymph nodes," and consists of multiple, irregular, unoriented fragments of yellow-brown, soft, fatty tissue (4.2 x 3 x 1.4 cm in aggregate). Multiple candidate lymph nodes are identified and the entire specimen is submitted as follow:

C1: One lymph node, bisected.
C2: Multiple candidate lymph nodes.
C3-C4:Remaining tissue.

Part D is received in formalin and additionally labeled "left pelvic lymph nodes," and consists of a

[page 3 of 3]
single, irregular, unoriented fragment of yellow-brown, soft, fatty tissue (5 x 3 x 1.6 cm). Multiple candidate lymph nodes are identified and the entire specimen is submitted as follow:

- D1: One lymph node, bisected.
D2: Multiple candidate lymph nodes.
D3: Remaining tissue.

Part E is received fresh, labeled "prostate and seminal vesicles," and consists of a prostate with attached seminal vesicles (55 gm; 3.5 cm from apex to base x 4.5 cm in width x 3.6 cm from anterior to posterior) and seminal vesicle/vas deferens bundles (right 4.8 x 2.4 x 1.2 cm; left 4.5 x 1.9 x 0.8 cm).

GROSS ABNORMALITIES: The posterior mid gland and posterior area near the base are firm with yellow-tan lobulated parenchyma. There is a 0.5 cm tan nodule on the left anterior mid gland (slide 2).

The remaining prostate is yellow-tan and homogeneous. The anterior fibrous stroma is open; the remaining capsule contains plastic surgical clips on the right and left seminal vesicles and right lateral bladder margin.

ORIENTED BY: Anatomic landmarks.

INKING: Anterior right green, anterior left blue, posterior black.

POTENTIAL STUDIES: Snap-frozen taken.

TOTAL NUMBER OF SLICES: 4.

AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins, entirely submitted in perpendicular sections

E1: Right apex.

E2: Left apex.

Right anterior quadrant

E3: Slice 2.

E4: Slice 3.

E5: Slice 4.

Right posterior quadrant

E6: Slice 2.

E7: Slice 3.

E8: Slice 4.

Left posterior quadrant

E9: Slice 2.

E10: Slice 3.

E11: Slice 4.

Left anterior quadrant

E12: Slice 2.

E13: Slice 3.

E14: Slice 4.

Bladder margins, entirely submitted in perpendicular sections

E15: Right.

E16: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

E17: Right.

E18: Left.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides. The attending pathologist has reviewed all dictations, including prosector work, and preliminary interpretations performed by any resident involved in the case and performed all necessary edits before signing the final report.

Electronically signed:

Criteria	hu 1/8/14	Yes	No

Source: NCI Genomic Data Commons file 188e9472-7375-4eb9-b969-73d3bcc3a36d (TCGA-V1-A9Z7.E50B8F61-E948-417F-A5B6-2C087A8D2B01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).